Somatic mutation profile of tumor specimen MP2PRT-PAUJYA-TMP1-A (aliquot MP2PRT-PAUJYA-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUJYA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,194 days).
Specimen MP2PRT-PAUJYA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2a0b70a-d446-4378-837b-6089a12cd5d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJYA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJYA-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d2e0a77-a93e-42d9-a95a-bad16893114a

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 116/328 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.2231G>C p.S744T (on ENST00000506720 / NM_001322402.2; = p.S676T on NM_015236.6) | Missense Mutation (SNP) | VAF 152/379 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as COSV72230564; called by muse, mutect2
- LLGL1 | c.2741C>T p.S914L | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1419371061, COSV57500088; called by muse, mutect2, varscan2
- PLEC | c.7630C>T p.R2544W (on ENST00000322810 / NM_201380.4; = p.R2434W on NM_000445.5) | Missense Mutation (SNP) | VAF 18/610 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs782255835; called by muse, mutect2
- RBM6 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 198/456 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.147); catalogued as rs774550181; called by muse, mutect2, varscan2
- SYMPK | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 168/382 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs760395766; called by muse, mutect2, varscan2
- VCAN | c.6935G>A p.G2312E | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.162); catalogued as COSV54115000; called by muse, mutect2
- ZNF676 | c.650C>A p.T217N (on ENST00000650058; = p.T185N on NM_001001411.3) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs751068129; called by muse, varscan2
- ATP2B1 | c.2827G>A p.V943I | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CALML6 | c.215G>C p.S72T | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- LMOD1 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 151/460 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- KIF1A | c.822G>A p.S274= | Silent (SNP) | VAF 125/462 reads (27%) | catalogued as rs553008418, COSV100240540; called by muse, mutect2, varscan2
